Somatic mutation profile of tumor specimen TCGA-66-2769-01A (aliquot TCGA-66-2769-01A-02W-0877-08) from TCGA case TCGA-66-2769, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 75.3 years (27,515 days).
Specimen TCGA-66-2769-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf119414-95ce-4014-a8d6-9bc6c4275fe9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2769-11A (Solid Tissue Normal), aliquot TCGA-66-2769-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87f6efec-adf5-4f5c-80c3-c14cc226d398

The open-access MAF lists 354 somatic variants for this specimen: 267 protein-altering or splice-affecting, 79 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 234, Silent 79, Nonsense Mutation 19, Intron 5, Frame Shift Ins 4, Frame Shift Del 4, Splice Site 3, Splice Region 3, RNA 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.2460C>G p.I820M | Missense Mutation (SNP) | VAF 129/1206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99685301; called by muse, mutect2, varscan2
- ABCG4 | c.810G>A p.K270= | Splice Region (SNP) | VAF 24/134 reads (18%) | catalogued as COSV100266663; called by muse, mutect2, varscan2
- ACTRT1 | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 101/378 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV100947547; called by muse, mutect2, varscan2
- ADAMTS19 | c.1436G>A p.G479D | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50740525, COSV99177111, COSV99179030; called by muse, mutect2, varscan2
- ADAMTS3 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99710704; called by muse, mutect2, varscan2
- ADAMTS9 | c.5695G>C p.V1899L | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.209); catalogued as COSV99899175; called by muse, mutect2, varscan2
- ADGRF5 | c.1167G>C p.L389F | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV51935134, COSV99345306; called by muse, mutect2
- ADGRG4 | c.2309C>A p.P770H | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV99795088; called by muse, mutect2, varscan2
- ADGRL3 | c.1016G>T p.G339V (on ENST00000506720 / NM_001322402.2; = p.G271V on NM_015236.6) | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101546982; called by muse, mutect2
- AGA | c.242A>T p.E81V | Missense Mutation (SNP) | VAF 140/316 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99219450; called by muse, mutect2, varscan2
- AGMO | c.1019T>C p.V340A | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1344644715, COSV100693958; called by muse, mutect2, varscan2
- AGTPBP1 | c.3364G>T p.E1122* (on ENST00000357081 / NM_001330701.2; = p.E1082* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as COSV100429577; called by muse, mutect2, varscan2
- AIM2 | c.897G>C p.E299D | Missense Mutation (SNP) | VAF 54/500 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV100931051; called by muse, mutect2, varscan2
- AIM2 | c.266A>G p.D89G | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.992); catalogued as COSV100931052; called by muse, mutect2, varscan2
- AKAP9 | c.8822A>T p.H2941L (on ENST00000359028; = p.H2917L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV100662222; called by mutect2, varscan2
- ALDH1L2 | c.1390A>T p.N464Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99310878; called by muse, mutect2, varscan2
- ALPK1 | c.2680G>A p.G894S | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs375839432; called by muse, mutect2, varscan2
- AMTN | c.456C>A p.S152R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100219746; called by muse, mutect2, varscan2
- ANK3 | c.665T>G p.L222R | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99779339; called by muse, mutect2, varscan2
- ANKAR | c.2527G>A p.V843I | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as COSV99854099; called by muse, mutect2
- ANKS1A | c.1165A>T p.K389* | Nonsense Mutation (SNP) | VAF 34/143 reads (24%) | catalogued as COSV100832249; called by muse, mutect2, varscan2
- APBA1 | c.837G>C p.Q279H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.201); catalogued as COSV99595811; called by muse, mutect2, varscan2
- APOB | c.1429G>C p.D477H | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV99264853; called by muse, mutect2
- APPBP2 | c.1355A>G p.H452R | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV99319585; called by muse, mutect2, varscan2
- ARHGAP21 | c.2903A>G p.H968R | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs761576609, COSV100256024; called by muse, mutect2, varscan2
- ARHGAP5 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.206); catalogued as COSV100565175; called by muse, mutect2, varscan2
- ARIH1 | c.1126C>G p.L376V | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV101158667; called by muse, mutect2, varscan2
- ASPM | c.9785C>G p.T3262R | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV99660053; called by muse, mutect2, varscan2
- ATN1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as rs1555143498, COSV100755742; called by muse, mutect2, varscan2
- ATP12A | c.2434G>A p.G812R | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.401); catalogued as rs772196577; called by muse, mutect2, varscan2
- BEND2 | c.1484C>A p.A495D | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV101191923; called by muse, mutect2, varscan2
- BLNK | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99813759; called by muse, mutect2, varscan2
- C21orf91 | c.857G>C p.R286P (on ENST00000284881 / NM_001100420.2; = p.R285P on NM_017447.4) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV99515988; called by muse, mutect2, varscan2
- C2CD5 | c.2084T>C p.L695P | Missense Mutation (SNP) | VAF 31/514 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100448619; called by muse, mutect2
- CACNA2D4 | c.1075A>T p.K359* | Nonsense Mutation (SNP) | VAF 25/234 reads (11%) | catalogued as rs1555185541, COSV99765426; called by muse, mutect2, varscan2
- CCDC88C | c.5094C>G p.D1698E | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.077); catalogued as COSV100484781; called by muse, mutect2, varscan2
- CELF4 | c.1282C>A p.L428M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100611444, COSV58454345; called by muse, mutect2, varscan2
- CENPE | c.5387T>C p.I1796T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.159); catalogued as COSV99477536; called by muse, mutect2, varscan2
- CENPQ | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100225695; called by muse, mutect2, varscan2
- CFAP20 | c.93T>G p.N31K | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.213); catalogued as COSV52630951, COSV99343441; called by muse, mutect2, varscan2
- CFAP65 | c.1226G>A p.C409Y | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55390201, COSV99838290; called by muse, mutect2
- CFAP77 | c.710A>G p.K237R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.14); catalogued as COSV100545721; called by muse, mutect2, varscan2
- CFAP91 | c.1317G>T p.L439F | Missense Mutation (SNP) | VAF 49/371 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV99847014; called by muse, mutect2, varscan2
- CHD5 | c.5028G>T p.E1676D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99313220; called by muse, mutect2, varscan2
- CHD7 | c.4100G>T p.R1367M | Missense Mutation (SNP) | VAF 145/890 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101418149; called by muse, mutect2, varscan2
- CHST5 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV100291859; called by muse, mutect2, varscan2
- CLIP4 | c.707A>G p.E236G | Missense Mutation (SNP) | VAF 51/324 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as COSV100191750; called by muse, mutect2, varscan2
- CLPTM1 | c.2000A>T p.K667I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100493718; called by muse, mutect2, varscan2
- COBL | c.2882T>C p.L961S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV99472102; called by muse, mutect2, varscan2
- COL6A6 | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100650133; called by muse, mutect2
- COL9A1 | c.1328G>C p.R443T | Missense Mutation (SNP) | VAF 52/586 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as COSV100294480; called by muse, mutect2
- CRYBG3 | c.8424C>G p.I2808M | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); catalogued as COSV99476835; called by muse, mutect2, varscan2
- CRYZ | c.875T>C p.I292T | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100558527; called by muse, mutect2, varscan2
- CTSO | c.394T>A p.C132S | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101467845, COSV70809612; called by muse, mutect2, varscan2
- CYP46A1 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV55896008, COSV99952554; called by muse, mutect2, varscan2
- DCAF12L1 | c.416G>T p.S139I | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV64421448; called by muse, mutect2, varscan2
- DGCR2 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99593521; called by muse, mutect2, varscan2
- DGKK | c.3313C>T p.L1105F | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101052949; called by muse, mutect2, varscan2
- DGKK | c.1859T>C p.I620T | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.986); catalogued as COSV101052950; called by muse, mutect2, varscan2
- DHX16 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs1009021407, COSV100906066; called by muse, mutect2, varscan2
- DNAH9 | c.8312T>A p.V2771E | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99305186; called by muse, mutect2
- DNAJC6 | c.763T>A p.C255S | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99674498; called by muse, mutect2, varscan2
- DPP4 | c.1541T>C p.L514P | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.685); catalogued as COSV100858792; called by muse, mutect2, varscan2
- DPRX | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 82/333 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs370339375, COSV100934071; called by muse, mutect2, varscan2
- DROSHA | c.2761_2762insT p.G921Vfs*23 | Frame Shift Ins (INS) | VAF 14/98 reads (14%) | catalogued as COSV100757560; called by mutect2, pindel, varscan2
- DYRK4 | c.581T>A p.M194K | Missense Mutation (SNP) | VAF 33/462 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs775366755, COSV99155967; called by muse, mutect2
- ELN | c.1523G>C p.G508A | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV99332471; called by muse, mutect2, varscan2
- ENOX2 | c.394G>C p.V132L (on ENST00000338144 / NM_001382520.1; = p.V103L on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100584006; called by muse, mutect2, varscan2
- ENPP1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 53/314 reads (17%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.506); catalogued as rs201280142, COSV100719478; called by muse, mutect2, varscan2
- EXOC2 | c.1447G>T p.A483S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.162); catalogued as COSV100033334; called by muse, mutect2
- FAM47C | c.238A>T p.K80* | Nonsense Mutation (SNP) | VAF 38/66 reads (58%) | catalogued as COSV100792431; called by muse, mutect2, varscan2
- FAT3 | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.182); catalogued as COSV53157254, COSV99964424; called by muse, mutect2, varscan2
- FBXO47 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV100960662; called by muse, mutect2, varscan2
- FCRL5 | c.1889G>C p.G630A | Missense Mutation (SNP) | VAF 98/823 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100708763, COSV62519924; called by muse, mutect2, varscan2
- FCRLA | c.322C>A p.P108T (on ENST00000367959; = p.P85T on NM_032738.4) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as COSV99375868; called by muse, mutect2, varscan2
- FOXM1 | c.777G>C p.L259F | Missense Mutation (SNP) | VAF 17/584 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100700827; called by muse, mutect2
- FRAS1 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.184); catalogued as COSV99350362; called by muse, mutect2
- FRMD5 | c.629A>C p.H210P | Missense Mutation (SNP) | VAF 43/409 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101296380; called by muse, mutect2, varscan2
- FRMPD2 | c.1456C>G p.Q486E | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.781); catalogued as COSV100563712, COSV59715123; called by muse, mutect2, varscan2
- GAK | c.2021T>C p.V674A | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100033396; called by muse, mutect2, varscan2
- GAK | c.2020G>T p.V674L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV100033398; called by muse, mutect2, varscan2
- GLA | c.1021del p.E341Nfs*7 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | catalogued as CD942143, CM160939, CM990695; called by mutect2, pindel, varscan2
- GORAB | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.492); catalogued as rs1269043222, COSV100883820, COSV63029140; called by muse, mutect2, varscan2
- GPM6A | c.624C>A p.N208K | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as rs769500100, COSV99703461; called by muse, mutect2, varscan2
- GPR160 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100576109; called by muse, mutect2
- GRIN2B | c.3543C>A p.H1181Q | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.187); catalogued as rs866476716, COSV101662994; called by muse, mutect2
- GRIP1 | c.1759A>T p.T587S (on ENST00000359742 / NM_001379345.1; = p.T535S on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV99668955, COSV99669736; called by mutect2, varscan2
- GRIP2 | c.1024G>T p.G342* (on ENST00000619221; = p.G245* on NM_001080423.4) | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV99817161; called by muse, mutect2, varscan2
- GUCY1B1 | c.1226A>G p.K409R | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1264814361, COSV100025469; called by muse, mutect2, varscan2
- HIF1A | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100048721; called by muse, mutect2, varscan2
- HJV | c.352A>T p.N118Y (on ENST00000336751 / NM_213653.4; = p.N5Y on NM_145277.5) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100382259, COSV60952027; called by muse, mutect2, varscan2
- HMCN1 | c.7645A>G p.T2549A | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs753619725, COSV99627243; called by muse, mutect2, varscan2
- HMCN1 | c.15428G>C p.R5143T | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99627252; called by muse, mutect2, varscan2
- HOXB9 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 69/285 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100239496, COSV60816833; called by muse, mutect2, varscan2
- HSPA12A | c.962T>C p.V321A | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs1554878548, COSV100979751; called by muse, mutect2
- HSPA13 | c.1193A>G p.E398G | Missense Mutation (SNP) | VAF 43/378 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV99579973; called by muse, mutect2, varscan2
- IFT140 | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs139286030; called by muse, mutect2, varscan2
- IGF2BP3 | c.1325C>G p.A442G | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV99325239; called by muse, mutect2
- INO80 | c.364A>G p.S122G | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.079); catalogued as COSV100731719; called by muse, mutect2, varscan2
- ITGAD | c.2649C>G p.Y883* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV101210419; called by muse, mutect2, varscan2
- ITIH6 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV54486235; called by muse, mutect2, varscan2
- JPH1 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.98); catalogued as rs761018173, COSV100646519; called by muse, mutect2
- KCNA5 | c.1039C>A p.P347T | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99363794; called by muse, mutect2
- KIAA0319 | c.1956C>G p.D652E | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100985436; called by muse, mutect2, varscan2
- KIAA1109 | c.12247G>T p.E4083* | Nonsense Mutation (SNP) | VAF 5/80 reads (6%) | catalogued as COSV52668108; called by muse, mutect2
- KIAA1217 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.194); catalogued as COSV100907939; called by muse, mutect2, varscan2
- KIF5B | c.2306+1G>A p.X769_splice | Splice Site (SNP) | VAF 17/125 reads (14%) | catalogued as COSV100191721; called by muse, mutect2, varscan2
- KIF6 | c.970T>G p.L324V | Missense Mutation (SNP) | VAF 51/490 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV99758230; called by muse, mutect2, varscan2
- KMT2E | c.2768G>T p.C923F | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV99996075; called by muse, mutect2, varscan2
- KRAS | c.367A>T p.R123* | Nonsense Mutation (SNP) | VAF 29/271 reads (11%) | catalogued as COSV99774742; called by muse, mutect2, varscan2
- KTN1 | c.1937T>C p.L646S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.026); catalogued as COSV101255101; called by muse, mutect2, varscan2
- LCOR | c.2958T>A p.H986Q | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99616764; called by muse, mutect2, varscan2
- LMAN1L | c.631C>G p.P211A | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.067); catalogued as COSV100547646; called by muse, mutect2, varscan2
- LRRC28 | c.509G>A p.W170* | Nonsense Mutation (SNP) | VAF 55/251 reads (22%) | catalogued as COSV100113474; called by muse, mutect2, varscan2
- MAGEA12 | c.262A>T p.S88C | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100756873; called by muse, mutect2, varscan2
- MAGEB1 | c.587C>A p.P196H | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100974917; called by muse, mutect2, varscan2
- MAGEB4 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV100974916, COSV66775861; called by muse, mutect2, varscan2
- MAGED1 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.679); catalogued as COSV100431490, COSV58517022; called by muse, mutect2, varscan2
- MAP2 | c.1295A>G p.E432G | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.433); catalogued as rs1361667762, COSV99559110; called by muse, mutect2
- MAP7D2 | c.985A>C p.M329L | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV101107290; called by muse, mutect2, varscan2
- MARK1 | c.124C>G p.R42G | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV65072027; called by muse, mutect2, varscan2
- MC2R | c.838A>T p.S280C | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100562960; called by muse, mutect2, varscan2
- MED12 | c.5936C>G p.S1979C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.356); catalogued as COSV100377195; called by muse, mutect2, varscan2
- MEX3C | c.1064A>C p.Q355P | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101346224; called by muse, mutect2, varscan2
- MIOS | c.2293G>C p.G765R | Missense Mutation (SNP) | VAF 93/398 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV100402662; called by muse, mutect2, varscan2
- MIPEP | c.752T>C p.I251T | Missense Mutation (SNP) | VAF 14/247 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs1279111735; called by muse, mutect2
- MKI67 | c.7151G>T p.G2384V | Missense Mutation (SNP) | VAF 244/694 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.284); catalogued as COSV100896391, COSV100897088; called by muse, mutect2, varscan2
- MLF2 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV99180068; called by muse, mutect2
- MMP16 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs147772248; called by muse, mutect2, varscan2
- MMRN2 | c.1236C>G p.I412M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV100922547; called by muse, mutect2, varscan2
- MTFR1 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.328); catalogued as COSV100050134; called by muse, mutect2, varscan2
- MUC16 | c.42027C>G p.I14009M | Missense Mutation (SNP) | VAF 123/395 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.971); catalogued as rs1271188716, COSV66693663; called by muse, mutect2, varscan2
- MUC16 | c.23173C>T p.P7725S | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV101199324; called by muse, mutect2, varscan2
- MUC16 | c.15412C>T p.H5138Y | Missense Mutation (SNP) | VAF 49/345 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.52); catalogued as COSV101199325, COSV67465684; called by muse, mutect2, varscan2
- MUC17 | c.13215C>G p.I4405M | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV100072636; called by muse, mutect2, varscan2
- NADSYN1 | c.1220A>G p.D407G | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100034612; called by muse, mutect2
- NAV2 | c.1558G>C p.D520H (on ENST00000396087 / NM_001244963.2; = p.D497H on NM_145117.5) | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100585455; called by muse, mutect2
- NAV3 | c.5803C>G p.Q1935E (on ENST00000397909 / NM_001024383.2; = p.Q1913E on NM_014903.6) | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV99889259; called by muse, mutect2, varscan2
- NDE1 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100706911; called by muse, mutect2
- NECTIN4 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.908); catalogued as COSV100919871; called by muse, mutect2, varscan2
- NEIL3 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52812124, COSV99220210; called by muse, mutect2, varscan2
- NELL1 | c.1983T>C p.D661= | Splice Region (SNP) | VAF 22/241 reads (9%) | catalogued as COSV100120433; called by muse, mutect2
- NFXL1 | c.1306G>A p.G436S | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100216707; called by muse, mutect2, varscan2
- NLRP2 | c.362A>C p.D121A | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV54759866, COSV99672136; called by muse, mutect2, varscan2
- NLRX1 | c.2581G>C p.E861Q | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99424076; called by muse, mutect2, varscan2
- NOTCH3 | c.6008A>G p.H2003R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99656712; called by muse, varscan2
- NR5A2 | c.667C>A p.L223I (on ENST00000367362 / NM_205860.3; = p.L177I on NM_003822.5) | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99370965; called by muse, mutect2, varscan2
- NRP1 | c.1590G>A p.M530I | Missense Mutation (SNP) | VAF 179/1099 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.034); catalogued as COSV99588281; called by muse, mutect2, varscan2
- OR10AG1 | c.140A>G p.Q47R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs762743781, COSV100400030; called by muse, mutect2, varscan2
- OR10G4 | c.833T>C p.L278P | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100304774, COSV57977824; called by muse, mutect2
- OR10G7 | c.371C>A p.A124D | Missense Mutation (SNP) | VAF 89/595 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100389879; called by muse, mutect2, varscan2
- OR1L4 | c.460C>A p.H154N | Missense Mutation (SNP) | VAF 144/657 reads (22%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.644); catalogued as COSV99413840; called by muse, mutect2, varscan2
- OR2D2 | c.193A>G p.N65D | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV100203784; called by muse, mutect2
- OR4Q3 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.543); catalogued as COSV100056922; called by muse, mutect2
- OR8G1 | c.519G>C p.L173F | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV100422353; called by muse, mutect2
- OR8U1 | c.403G>T p.V135L | Missense Mutation (SNP) | VAF 87/332 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100163857; called by muse, varscan2
- P3H4 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV100387811; called by muse, mutect2, varscan2
- PCDHB4 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as COSV52020391, COSV52026805; called by mutect2, varscan2
- PCLO | c.6538G>T p.D2180Y | Missense Mutation (SNP) | VAF 81/332 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV100430324, COSV61656034; called by muse, mutect2, varscan2
- PDE1B | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV99672384; called by muse, mutect2, varscan2
- PKIG | c.26C>G p.S9W | Missense Mutation (SNP) | VAF 83/431 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100596102, COSV63069193; called by muse, mutect2, varscan2
- PKNOX2 | c.1263G>C p.M421I | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV100020603; called by muse, mutect2
- PLCB2 | c.3211T>C p.L1071= | Splice Region (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99541837; called by muse, mutect2, varscan2
- PLD1 | c.2092A>T p.I698F | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1349390378, COSV100577938; called by muse, mutect2
- PLXNA4 | c.295C>A p.R99S | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as COSV100323596, COSV104414485; called by muse, mutect2, varscan2
- PMPCB | c.1224G>C p.M408I | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV99971202; called by muse, mutect2
- PNLIPRP1 | c.513C>G p.S171R | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100724322; called by muse, mutect2
- PNPLA6 | c.1729C>T p.P577S (on ENST00000414982 / NM_001166111.2; = p.P529S on NM_006702.5) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as COSV99653463; called by muse, mutect2, varscan2
- PRKAG2 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 13/125 reads (10%) | catalogued as COSV55226537; called by muse, mutect2, varscan2
- PRMT9 | c.1648C>A p.P550T | Missense Mutation (SNP) | VAF 19/500 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.052); catalogued as COSV59360526; called by muse, mutect2
- PRPF39 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 14/156 reads (9%) | catalogued as COSV100866002; called by muse, mutect2
- PRUNE2 | c.8939A>G p.K2980R | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as COSV99795987; called by muse, mutect2, varscan2
- PSMD1 | c.1950C>A p.Y650* | Nonsense Mutation (SNP) | VAF 19/140 reads (14%) | catalogued as COSV100433484; called by muse, mutect2, varscan2
- PSMD1 | c.1951G>C p.G651R | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100433485; called by muse, mutect2, varscan2
- PTPRD | c.1536G>C p.Q512H | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV100644148, COSV61965957; called by muse, mutect2, varscan2
- RAB11FIP1 | c.751G>T p.G251* | Nonsense Mutation (SNP) | VAF 53/428 reads (12%) | catalogued as COSV99769905; called by muse, mutect2, varscan2
- RASD2 | c.675G>T p.M225I | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99332736; called by muse, mutect2, varscan2
- RBFOX2 | c.1328G>C p.G443A (on ENST00000438146 / NM_001349995.2; = p.V356L on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV99455259; called by muse, mutect2, varscan2
- RELN | c.3530G>C p.S1177T | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.054); catalogued as COSV100633206; called by muse, mutect2, varscan2
- RELN | c.2864A>T p.N955I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100633208; called by muse, mutect2, varscan2
- RGL1 | c.449C>T p.A150V (on ENST00000360851 / NM_001297672.2; = p.A185V on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV100486420; called by muse, mutect2, varscan2
- RGN | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as rs782235261, COSV100282419, COSV60276264; called by muse, mutect2, varscan2
- RIPOR2 | c.1456T>C p.S486P | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.354); catalogued as COSV99428901; called by muse, mutect2, varscan2
- ROR1 | c.2624G>T p.G875V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV100935132; called by muse, mutect2, varscan2
- RPL10A | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV100003284; called by muse, mutect2
- RTF2 | c.467T>A p.V156D | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99196473; called by muse, mutect2
- RXFP3 | c.283G>C p.G95R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100347277, COSV100347460; called by muse, mutect2, varscan2
- RYR2 | c.2148T>A p.N716K | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100769333; called by muse, mutect2
- SAMD4B | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100080228; called by muse, mutect2
- SCARB1 | c.1358G>T p.C453F | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.516); catalogued as COSV99909102; called by muse, mutect2, varscan2
- SCN7A | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as rs1474665417, COSV101313159; called by mutect2, varscan2
- SCUBE1 | c.1796C>G p.S599* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100683092; called by muse, mutect2, varscan2
- SEC11A | c.366C>G p.D122E | Missense Mutation (SNP) | VAF 46/470 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99189991; called by muse, mutect2
- SETBP1 | c.319A>T p.I107F | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750263138, COSV99952709; called by muse, mutect2, varscan2
- SF3A3 | c.1335C>G p.H445Q | Missense Mutation (SNP) | VAF 124/900 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100885623; called by muse, mutect2, varscan2
- SHC3 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101011915; called by muse, mutect2, varscan2
- SIAH2 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100469192, COSV57262725; called by muse, mutect2, varscan2
- SLC12A1 | c.1935G>C p.K645N | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.35); catalogued as COSV101118491; called by muse, mutect2, varscan2
- SLC18B1 | c.1290T>A p.Y430* | Nonsense Mutation (SNP) | VAF 32/104 reads (31%) | catalogued as COSV51594542, COSV99259039; called by muse, mutect2, varscan2
- SLC19A3 | c.1304T>C p.V435A | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV51451677; called by muse, mutect2
- SLC25A38 | c.436G>C p.V146L | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV99827819; called by muse, mutect2, varscan2
- SLC7A6 | c.585C>G p.F195L | Missense Mutation (SNP) | VAF 74/389 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99546514; called by muse, mutect2, varscan2
- SLCO1A2 | c.1252A>G p.I418V | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100261618; called by muse, mutect2, varscan2
- SLF1 | c.2186C>G p.S729* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99475764; called by muse, mutect2, varscan2
- SMPDL3A | c.636G>C p.L212F | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100868682, COSV63755191; called by muse, mutect2, varscan2
- SPAG16 | c.1388G>T p.W463L | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1484009851, COSV100531284; called by muse, mutect2, varscan2
- SPHKAP | c.1181A>T p.N394I | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100763982; called by muse, mutect2, varscan2
- SRGAP3 | c.1590C>G p.I530M | Missense Mutation (SNP) | VAF 67/393 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100840874, COSV64533174; called by muse, mutect2, varscan2
- SVEP1 | c.8153A>T p.D2718V | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.399); catalogued as COSV99928770; called by muse, mutect2, varscan2
- TALDO1 | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.51); catalogued as COSV100032548; called by muse, mutect2, varscan2
- TAS2R39 | c.1002A>T p.K334N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV101489403; called by muse, mutect2, varscan2
- TBC1D31 | c.110A>C p.D37A | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99782642; called by muse, mutect2
- TBX4 | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 73/116 reads (63%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.863); catalogued as COSV99540078; called by muse, varscan2
- TCTN1 | c.239G>C p.C80S | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100885952; called by muse, mutect2
- TDO2 | c.508A>T p.N170Y | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV101539727; called by muse, mutect2, varscan2
- TERF1 | c.416-1G>C p.X139_splice | Splice Site (SNP) | VAF 14/54 reads (26%) | catalogued as COSV99401091; called by muse, mutect2, varscan2
- TEX14 | c.3110G>C p.R1037T (on ENST00000240361 / NM_001201457.2; = p.R1031T on NM_031272.5) | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as COSV99541897; called by muse, mutect2, varscan2
- TIMM50 | c.686A>T p.H229L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV100067877; called by muse, mutect2, varscan2
- TLN2 | c.3448G>A p.A1150T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as rs765379062, COSV100168642, COSV60893469; called by muse, mutect2, varscan2
- TLR10 | c.2015T>G p.F672C | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100457540; called by muse, mutect2, varscan2
- TM7SF3 | c.1480C>G p.L494V | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100544743; called by muse, mutect2
- TM9SF3 | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 48/348 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs1326896260, COSV100951837; called by muse, mutect2, varscan2
- TMEM248 | c.277C>A p.Q93K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV100447293, COSV100447454; called by muse, mutect2, varscan2
- TMEM74 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 18/128 reads (14%) | catalogued as rs765862143, COSV99865578; called by muse, mutect2, varscan2
- TNFRSF14 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as COSV100859111; called by muse, mutect2, varscan2
- TNR | c.650G>C p.G217A | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54920934, COSV99688822; called by muse, mutect2, varscan2
- TONSL | c.2015-2A>G p.X672_splice | Splice Site (SNP) | VAF 3/34 reads (9%) | catalogued as COSV101340197; called by muse, mutect2
- TRHDE | c.1894C>T p.L632F | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99670124; called by muse, mutect2
- TRIAP1 | c.58A>C p.N20H | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as COSV99985015; called by muse, mutect2, varscan2
- TRIM3 | c.1146G>T p.K382N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.652); catalogued as COSV61984406; called by muse, mutect2, varscan2
- TSSK2 | c.825dup p.K276Qfs*21 | Frame Shift Ins (INS) | VAF 6/42 reads (14%) | catalogued as rs764514103; called by pindel, varscan2
- TTN | c.93348C>A p.H31116Q (on ENST00000591111; = p.H23692Q on NM_003319.4) | Missense Mutation (SNP) | VAF 12/110 reads (11%) | PolyPhen benign (0.396); catalogued as COSV100604392, COSV60173177; called by muse, mutect2, varscan2
- TTN | c.67754C>A p.P22585H (on ENST00000591111; = p.P15161H on NM_003319.4) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | PolyPhen probably damaging (0.999); catalogued as COSV100604394; called by muse, mutect2, varscan2
- TYK2 | c.716G>C p.R239P | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV53387649; called by mutect2, varscan2
- UBA2 | c.1260A>T p.K420N | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as COSV99875421; called by muse, mutect2
- UBE3C | c.1464G>A p.M488I | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV100779893; called by muse, varscan2
- UBQLN2 | c.510G>T p.Q170H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV100592684; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1408G>T p.V470F | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99691380; called by muse, mutect2, varscan2
- USH2A | c.14666G>A p.G4889E | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100232585, COSV56383561; called by muse, mutect2, varscan2
- USP15 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV54798006, COSV99739097; called by muse, mutect2
- VPS4B | c.1041T>A p.D347E | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV99447851; called by muse, mutect2
- VWF | c.8137G>T p.G2713C | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99778653; called by muse, mutect2, varscan2
- WIPF2 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1465801704, COSV60276495; called by muse, mutect2, varscan2
- WIPI2 | c.1181C>G p.P394R | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV99993256, COSV99993527; called by muse, mutect2, varscan2
- YAP1 | c.1388T>G p.M463R (on ENST00000282441 / NM_001130145.3; = p.M409R on NM_006106.5) | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99176076; called by muse, mutect2, varscan2
- ZBBX | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 104/773 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100283697; called by muse, mutect2, varscan2
- ZDBF2 | c.6843G>T p.E2281D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as COSV100984608; called by muse, mutect2, varscan2
- ZFHX4 | c.3266C>T p.P1089L | Missense Mutation (SNP) | VAF 55/962 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as rs1424845782, COSV99259663, COSV99260964; called by muse, mutect2
- ZNF282 | c.1541G>T p.R514L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as COSV100021563, COSV100021774; called by muse, mutect2
- ZNF283 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1024961287, COSV100190437; called by muse, mutect2, varscan2
- ZNF45 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs201102768; called by muse, mutect2, varscan2
- ZNF804A | c.2450G>T p.G817V | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV100167284; called by muse, mutect2, varscan2
- ADGRA1 | c.70C>G p.Q24E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); called by muse, mutect2
- CCNDBP1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2
- CYP4F22 | c.1218_1219del p.R407Pfs*36 | Frame Shift Del (DEL) | VAF 58/328 reads (18%) | called by pindel, varscan2
- DEAF1 | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DGKA | c.942_948del p.V315Mfs*42 | Frame Shift Del (DEL) | VAF 50/258 reads (19%) | called by mutect2, pindel, varscan2
- HDHD3 | c.349del p.A117Lfs*5 | Frame Shift Del (DEL) | VAF 20/117 reads (17%) | called by mutect2, pindel, varscan2
- IGHG3 | c.86T>A p.V29D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, varscan2
- LCOR | c.4360G>C p.E1454Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- LILRA2 | c.1392dup p.I465Dfs*5 (on ENST00000391738 / NM_001130917.3; = p.I448Dfs*5 on NM_006866.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 35/151 reads (23%) | called by mutect2, pindel, varscan2
- NBR1 | c.1675G>C p.D559H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SALL2 | c.916T>G p.L306V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SEZ6L | c.1022A>G p.D341G | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.127); called by muse, mutect2
- VN1R5 | c.800C>A p.A267D | Missense Mutation (SNP) | VAF 69/264 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB11 | c.2631G>T p.M877I | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.273); called by muse, mutect2
- ZNF492 | c.129dup p.V44Sfs*29 | Frame Shift Ins (INS) | VAF 69/433 reads (16%) | called by mutect2, pindel, varscan2
- AC004922.1 | c.819C>T p.N273= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV99501070; called by muse, mutect2, varscan2
- AC005833.1 | c.1284A>G p.G428= | Silent (SNP) | VAF 34/744 reads (5%) | catalogued as COSV99362691; called by muse, mutect2
- ACADSB | c.1248T>C p.A416= | Silent (SNP) | VAF 26/269 reads (10%) | catalogued as COSV100715132; called by muse, mutect2, varscan2
- AFG1L | c.1347C>T p.T449= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs776358723, COSV64556752; called by muse, mutect2, varscan2
- AGBL5 | c.1191G>A p.Q397= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100549009; called by muse, mutect2, varscan2
- CACFD1 | c.132C>A p.I44= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99390209; called by muse, mutect2, varscan2
- CBY2 | c.42T>C p.L14= | Silent (SNP) | VAF 31/385 reads (8%) | catalogued as COSV100137562; called by muse, mutect2
- CCNB3 | c.1302A>G p.E434= | Silent (SNP) | VAF 9/107 reads (8%) | catalogued as rs375406438, COSV99328812; called by muse, mutect2
- CDH18 | c.1023G>A p.K341= | Silent (SNP) | VAF 16/172 reads (9%) | catalogued as rs746799767, COSV99933591, COSV99938325; called by muse, mutect2
- CLCNKA | c.1269C>T p.A423= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs532394987, COSV100509986; called by muse, mutect2, varscan2
- CLTC | c.3216C>T p.F1072= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV99291996; called by muse, mutect2, varscan2
- CNR2 | c.507C>A p.L169= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100991283; called by muse, mutect2, varscan2
- CSMD3 | c.10071G>T p.V3357= (on ENST00000297405 / NM_001363185.1; = p.V3188= on NM_052900.3) | Silent (SNP) | VAF 119/710 reads (17%) | catalogued as COSV99830661; called by muse, mutect2, varscan2
- CYP4B1 | c.12C>T p.S4= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs113351559, COSV99596979; called by muse, mutect2, varscan2
- CYTL1 | c.378A>T p.P126= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as COSV100312373; called by muse, mutect2, varscan2
- DGKD | c.1647T>A p.L549= (on ENST00000264057 / NM_152879.3; = p.L505= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/328 reads (16%) | catalogued as COSV99895984; called by muse, mutect2, varscan2
- DNAJC21 | c.999G>A p.E333= | Silent (SNP) | VAF 58/547 reads (11%) | catalogued as COSV100331331; called by muse, mutect2, varscan2
- DST | c.21498C>T p.A7166= (on ENST00000361203 / NM_001374722.1; = p.A4863= on NM_015548.5) | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as rs554828969, COSV99753955; ClinVar: likely benign; called by muse, mutect2
- EGFLAM | c.747C>A p.P249= | Silent (SNP) | VAF 17/162 reads (10%) | catalogued as COSV100380150, COSV59312144; called by muse, mutect2, varscan2
- ELOA2 | c.447C>T p.R149= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs778714672, COSV55300207; called by mutect2, varscan2
- ETS1 | c.738C>A p.L246= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as COSV60097609; called by muse, mutect2, varscan2
- FAM135B | c.3219C>A p.S1073= | Silent (SNP) | VAF 14/284 reads (5%) | catalogued as COSV52701706, COSV52732190, COSV99421948; called by muse, mutect2
- FBN2 | c.6834G>A p.T2278= | Silent (SNP) | VAF 29/410 reads (7%) | catalogued as rs374853253; ClinVar: likely benign; called by muse, mutect2
- FCRL6 | c.750C>T p.N250= | Silent (SNP) | VAF 85/355 reads (24%) | catalogued as COSV100220143; called by muse, mutect2, varscan2
- FIGNL1 | c.606A>T p.T202= | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as COSV100794872; called by muse, mutect2
- FSTL5 | c.1158C>A p.S386= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV100054060; called by muse, mutect2, varscan2
- GAS2L3 | c.204A>T p.A68= | Silent (SNP) | VAF 37/254 reads (15%) | catalogued as COSV99902795; called by muse, mutect2, varscan2
- GGCX | c.1419C>T p.I473= | Silent (SNP) | VAF 19/239 reads (8%) | catalogued as rs1203139224, COSV99289837; called by muse, mutect2
- GRXCR1 | c.660A>T p.S220= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as COSV101295647; called by muse, mutect2, varscan2
- HDAC1 | c.315C>G p.G105= | Silent (SNP) | VAF 22/254 reads (9%) | catalogued as COSV101000374; called by muse, mutect2
- HSD17B2 | c.258G>A p.L86= | Silent (SNP) | VAF 45/286 reads (16%) | catalogued as COSV99556547; called by muse, mutect2, varscan2
- HUNK | c.1527T>C p.D509= | Silent (SNP) | VAF 40/326 reads (12%) | catalogued as COSV99528317; called by muse, mutect2
- INTS5 | c.2058G>A p.K686= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100399549; called by muse, mutect2, varscan2
- ISLR2 | c.1977G>A p.P659= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV62303196; called by muse, mutect2
- ITPR2 | c.6384A>G p.P2128= | Silent (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- JADE2 | c.1560C>A p.S520= | Silent (SNP) | VAF 10/151 reads (7%) | catalogued as COSV99253019; called by muse, mutect2
- JCHAIN | c.411A>G p.P137= | Silent (SNP) | VAF 19/206 reads (9%) | catalogued as COSV99636386; called by muse, mutect2
- KCNU1 | c.939A>G p.E313= | Silent (SNP) | VAF 53/127 reads (42%) | catalogued as COSV101299111; called by muse, mutect2, varscan2
- KDM7A | c.825A>G p.Q275= | Silent (SNP) | VAF 35/156 reads (22%) | catalogued as rs915842554, COSV50090426; called by muse, mutect2, varscan2
- KIAA1191 | c.621C>G p.T207= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as COSV100055373; called by muse, mutect2, varscan2
- KRT6C | c.1566C>T p.G522= | Silent (SNP) | VAF 33/186 reads (18%) | catalogued as COSV99359924; called by muse, mutect2, varscan2
- LILRB1 | c.1617C>A p.G539= (on ENST00000427581; = p.G489= on NM_006669.6) | Silent (SNP) | VAF 79/315 reads (25%) | catalogued as COSV100207154; called by muse, mutect2, varscan2
- LMO3 | c.393C>T p.Y131= | Silent (SNP) | VAF 22/310 reads (7%) | catalogued as rs770032655, COSV53782977; called by muse, mutect2
- LTV1 | c.585T>C p.D195= | Silent (SNP) | VAF 35/284 reads (12%) | catalogued as COSV100849564; called by muse, mutect2, varscan2
- MAGEB1 | c.588C>A p.P196= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as COSV100974919; called by muse, mutect2, varscan2
- MBIP | c.1020C>G p.T340= | Silent (SNP) | VAF 80/495 reads (16%) | catalogued as rs1385910382, COSV100576757, COSV100576825; called by muse, mutect2, varscan2
- MUC16 | c.33108T>A p.P11036= | Silent (SNP) | VAF 193/683 reads (28%) | catalogued as COSV101199323; called by muse, mutect2, varscan2
- MYH1 | c.4245T>C p.C1415= | Silent (SNP) | VAF 81/307 reads (26%) | catalogued as COSV99875483; called by muse, mutect2, varscan2
- NFKB2 | c.333C>T p.G111= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99502958; called by muse, mutect2, varscan2
- NTSR2 | c.546G>T p.T182= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100183812, COSV100183865; called by muse, mutect2
- OR10G7 | c.372C>T p.A124= | Silent (SNP) | VAF 87/597 reads (15%) | catalogued as COSV100389877; called by muse, mutect2, varscan2
- OR1L4 | c.459C>A p.S153= | Silent (SNP) | VAF 147/657 reads (22%) | catalogued as COSV99413838; called by muse, mutect2, varscan2
- OR2G6 | c.426G>A p.A142= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as rs754561742, COSV58574602; called by muse, mutect2, varscan2
- OR2T2 | c.819A>G p.K273= | Silent (SNP) | VAF 16/178 reads (9%) | catalogued as COSV100737629; called by muse, mutect2, varscan2
- OR4K14 | c.342G>T p.V114= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV100520376; called by muse, mutect2, varscan2
- P3H4 | c.537C>A p.A179= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV100387810; called by muse, mutect2, varscan2
- PCDHA12 | c.723G>A p.A241= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as rs1554168359, COSV56543416; called by muse, mutect2
- PEX5L | c.1530A>G p.L510= | Silent (SNP) | VAF 24/303 reads (8%) | catalogued as COSV99828379; called by muse, mutect2
- PRDX6 | c.390A>T p.T130= | Silent (SNP) | VAF 61/269 reads (23%) | catalogued as COSV100458455, COSV100458534; called by muse, mutect2, varscan2
- RFXANK | c.738C>A p.I246= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as COSV100284490; called by muse, mutect2, varscan2
- RGS7 | c.924C>T p.S308= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as rs550551879, COSV100466231; called by muse, mutect2, varscan2
- ROR1 | c.2625A>G p.G875= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs755448829, COSV100935133; called by muse, mutect2, varscan2
- SLC6A4 | c.1794C>T p.I598= | Silent (SNP) | VAF 12/202 reads (6%) | catalogued as COSV55567650; called by muse, mutect2
- SMARCAL1 | c.630C>T p.S210= | Silent (SNP) | VAF 7/184 reads (4%) | called by muse, mutect2
- SMCO4 | c.55C>A p.R19= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs140592708, COSV100127888, COSV54360616; called by muse, mutect2, varscan2
- SNED1 | c.4063A>C p.R1355= | Silent (SNP) | VAF 57/490 reads (12%) | catalogued as COSV99612462; called by muse, mutect2, varscan2
- SPACA1 | c.564T>C p.N188= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1349935930, COSV99389467; called by muse, mutect2, varscan2
- SPINK5 | c.1308G>A p.L436= | Silent (SNP) | VAF 73/213 reads (34%) | catalogued as rs1253434551, COSV99806481; called by muse, mutect2, varscan2
- STAB2 | c.4968C>A p.P1656= | Silent (SNP) | VAF 45/405 reads (11%) | called by muse, mutect2, varscan2
- SYNE1 | c.10206C>T p.S3402= (on ENST00000367255 / NM_182961.4; = p.S3409= on NM_033071.3) | Silent (SNP) | VAF 38/164 reads (23%) | catalogued as rs1158144490, COSV99559344; called by muse, mutect2, varscan2
- SYNE2 | c.16776T>C p.I5592= | Silent (SNP) | VAF 34/169 reads (20%) | catalogued as COSV100647324; called by muse, mutect2, varscan2
- SYNPO2 | c.1554A>T p.P518= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV100205309; called by muse, mutect2, varscan2
- TBC1D21 | c.129C>A p.A43= | Silent (SNP) | VAF 99/480 reads (21%) | catalogued as COSV100311268; called by muse, mutect2, varscan2
- TMEM131 | c.2685G>A p.L895= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV51773429, COSV99487350, COSV99489233; called by muse, mutect2, varscan2
- TNS3 | c.2616G>C p.L872= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV100235331; called by muse, mutect2, varscan2
- TP63 | c.1263G>C p.L421= | Silent (SNP) | VAF 18/304 reads (6%) | catalogued as COSV99286404; called by muse, mutect2
- ZMIZ1 | c.3126G>A p.E1042= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV100566036; called by muse, mutect2, varscan2
- ZNF708 | c.1005C>A p.P335= | Silent (SNP) | VAF 15/188 reads (8%) | catalogued as COSV100803032, COSV63608336; called by muse, mutect2
- ZSWIM8 | c.2193G>A p.A731= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs542136024, COSV101289857; called by muse, mutect2, varscan2
- ANKHD1 | c.1782+7463G>T | Intron (SNP) | VAF 18/117 reads (15%) | catalogued as COSV99782794; called by muse, mutect2, varscan2
- C1QTNF3 | c.84+95G>A | Intron (SNP) | VAF 39/522 reads (7%) | catalogued as rs201504297, COSV99180698; called by muse, mutect2
- MIR125B2 | n.36T>G | RNA (SNP) | VAF 89/125 reads (71%) | called by muse, mutect2, varscan2
- NALCN | c.2193-5739G>A | Intron (SNP) | VAF 4/64 reads (6%) | catalogued as rs1403597914; called by muse, mutect2
- SNORD115-31 | n.28C>A | RNA (SNP) | VAF 34/135 reads (25%) | called by muse, varscan2
- TTN | c.10361-5142G>T | Intron (SNP) | VAF 18/118 reads (15%) | catalogued as COSV100604398; called by muse, mutect2, varscan2
- TTN | c.10361-5143G>T | Intron (SNP) | VAF 18/118 reads (15%) | catalogued as COSV60126789; called by muse, mutect2, varscan2
- ZNF99 | c.*1077C>G | 3'UTR (SNP) | VAF 18/208 reads (9%) | catalogued as COSV101233784; called by muse, mutect2
